Somatic mutation profile of tumor specimen TCGA-3B-A9HT-01A (aliquot TCGA-3B-A9HT-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HT, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Tongue, NOS; Age at diagnosis: 53.8 years (19,637 days).
Specimen TCGA-3B-A9HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5578fb3e-a852-4450-837c-85482eecfaaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HT-10A (Blood Derived Normal), aliquot TCGA-3B-A9HT-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef557a53-5bd1-4e74-8db8-5b1ff775a9dc

The open-access MAF lists 349 somatic variants for this specimen: 272 protein-altering or splice-affecting, 70 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 70, Frame Shift Del 35, Frame Shift Ins 15, Nonsense Mutation 6, Intron 5, In Frame Del 2, RNA 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1350del p.L451Sfs*16 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs746723399, COSV59872823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GJB1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1241595912, CM970669, COSV62139915; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99771662; called by muse, mutect2
- ABCF1 | c.1195G>A p.G399R (on ENST00000326195 / NM_001025091.2; = p.G361R on NM_001090.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100401041; called by muse, mutect2, varscan2
- AC004593.2 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs774356951, COSV56099686; called by muse, mutect2, varscan2
- ACOT11 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100650775; called by muse, mutect2, varscan2
- AFDN | c.4516T>A p.S1506T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV100653494; called by muse, mutect2, varscan2
- AHNAK2 | c.6320T>C p.M2107T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100318821; called by muse, mutect2, varscan2
- ALS2CL | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs142502930; called by muse, varscan2
- ANKMY1 | c.1267T>G p.S423A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs766392162, COSV99801896, COSV99803121; called by muse, varscan2
- ANKRD13B | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as rs774030034, COSV67473645; called by muse, mutect2, varscan2
- ANKRD13C | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs771631682, COSV52028935; called by muse, mutect2, varscan2
- ANKRD28 | c.2752C>A p.L918I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as COSV101080891; called by mutect2, varscan2
- ANXA1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs376171580; called by muse, varscan2
- ANXA5 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99634670; called by muse, mutect2
- APOBR | c.2602C>G p.L868V (on ENST00000431282; = p.L877V on NM_018690.4) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs769897477, COSV100112905; called by muse, mutect2, varscan2
- ARHGAP31 | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs755634742, COSV51788683; called by muse, mutect2
- ARHGAP33 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); catalogued as rs756596582, COSV50126367; called by muse, mutect2, varscan2
- ARHGEF10L | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs780477750, COSV51443352; called by muse, mutect2, varscan2
- ARHGEF28 | c.3527G>A p.R1176H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889538743, COSV55256734; called by muse, mutect2, varscan2
- ARID5A | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777135656, COSV100673642; called by muse, varscan2
- ARIH2 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751798787, COSV100711397, COSV62706338; called by muse, mutect2
- ART1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs566663445, COSV51703489; called by muse, mutect2, varscan2
- ASIC2 | c.995del p.P332Lfs*16 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1567720056; called by mutect2, pindel, varscan2
- ATP11A | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99369833; called by muse, mutect2, varscan2
- ATP7B | c.3803G>T p.G1268V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD054308, COSV99666918; called by muse, varscan2
- BAIAP2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1028076093, COSV58338441; called by mutect2, varscan2
- BBOX1 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99589953; called by muse, mutect2, varscan2
- BCOR | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1180666937, COSV100654036; called by muse, mutect2
- BCOR | c.1005del p.S336Rfs*42 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as CD093233; called by mutect2, pindel, varscan2
- BDH2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1180401542, COSV99600795; called by muse, mutect2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BEX2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs1470330345, COSV65500828, COSV65500935; called by muse, mutect2, varscan2
- BMPER | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99780440; called by muse, mutect2, varscan2
- C5 | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs747046818, COSV99798614; called by muse, mutect2, varscan2
- CA2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271939346, COSV99570136; called by muse, mutect2, varscan2
- CACNA1F | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151203138, COSV59904563; called by muse, mutect2, varscan2
- CAPN15 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs772816675, COSV99562797; called by muse, varscan2
- CDC45 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs913329845, COSV99597010; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4273C>T p.R1425W | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs200356726, COSV62573841; called by muse, mutect2, varscan2
- CELSR1 | c.8296G>A p.V2766I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs757174874, COSV99419857; called by muse, mutect2, varscan2
- CEP152 | c.5108A>T p.D1703V (on ENST00000380950 / NM_001194998.2; = p.D1647V on NM_014985.4) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100359127; called by muse, mutect2, varscan2
- CEP72 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99375261; called by mutect2, varscan2
- CEP83 | c.1979T>C p.L660P | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99313741; called by muse, mutect2, varscan2
- CERK | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs144086274, COSV53450899; called by muse, mutect2, varscan2
- CFAP74 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1352527664, COSV54568806; called by muse, mutect2, varscan2
- CHRFAM7A | c.512_514del p.K171del | In Frame Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs770240511; called by pindel, varscan2
- CLU | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs771318822, COSV57066327; called by muse, mutect2, varscan2
- CMTR2 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as rs189091912, COSV100579335; called by muse, mutect2, varscan2
- CNDP2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs559463515, COSV60840654; called by muse, mutect2, varscan2
- CNNM1 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779616573, COSV100763843; called by mutect2, varscan2
- COL12A1 | c.6314G>A p.G2105D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV100486410; called by muse, mutect2, varscan2
- COMMD4 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99143151; called by muse, mutect2
- COMP | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as COSV99721564; called by muse, mutect2, varscan2
- CRYBG1 | c.1269del p.S424Rfs*44 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs779999459; called by mutect2, pindel, varscan2
- CSPG5 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99274133; called by muse, mutect2, varscan2
- CUL1 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1236894600, COSV57387036; called by muse, mutect2, varscan2
- CYP11B2 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs768685630, COSV100011321, COSV100011338; called by muse, mutect2, varscan2
- CYP2D6 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769351604, COSV100637375; called by muse, mutect2
- DAPK1 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV63794076; called by muse, mutect2, varscan2
- DCAF12 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100778405; called by muse, mutect2
- DCTN1 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1327106238, COSV62621480; called by muse, mutect2, varscan2
- DNAJC17 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as rs769832240, COSV99549182; called by muse, mutect2, varscan2
- DNMT3A | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs375399431, COSV53043522; called by muse, mutect2, varscan2
- DOC2A | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1231639597, COSV58751060; called by muse, mutect2, varscan2
- DRC7 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs147667972; called by muse, mutect2, varscan2
- DROSHA | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV100323636; called by muse, mutect2, varscan2
- ECHDC2 | c.715G>A p.V239M (on ENST00000371522 / NM_001198961.2; = p.V208M on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs374095939; called by muse, mutect2, varscan2
- EDC3 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs1304872108, COSV100166147; called by muse, mutect2, varscan2
- EDEM2 | c.1490A>T p.E497V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV100788033; called by muse, mutect2, varscan2
- EIF3L | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as rs1453440089, COSV101094675; called by muse, mutect2
- ENC1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV100188234; called by muse, mutect2, varscan2
- EPB41L4A | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376132286, COSV99814051; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- EXPH5 | c.1441del p.W481Gfs*29 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as rs1243483275; called by mutect2, pindel
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, pindel, varscan2
- FAT1 | c.7493A>T p.E2498V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.038); catalogued as COSV101499625; called by muse, mutect2, varscan2
- FBLN1 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.489); catalogued as rs772202085, COSV53054767; called by muse, mutect2, varscan2
- FGF17 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV63925912; called by muse, varscan2
- FGF3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1262110871, COSV61926261; called by muse, mutect2, varscan2
- GALNT10 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1036938665, COSV51722169; called by muse, mutect2, varscan2
- GLCE | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341974834, COSV99962604; called by muse, mutect2
- GLIPR1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99875884; called by muse, mutect2
- GNB2 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99309943; called by muse, mutect2, varscan2
- GPALPP1 | c.273dup p.G92Wfs*9 | Frame Shift Ins (INS) | VAF 19/163 reads (12%) | catalogued as rs762704412; called by mutect2, pindel, varscan2
- GPD2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs757181789, COSV100133636; called by muse, mutect2, varscan2
- GPHA2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs573463788, COSV51209758; called by muse, mutect2, varscan2
- GPR135 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs539098784, COSV101229348; called by muse, mutect2, varscan2
- GRWD1 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs771580285, COSV99474299, COSV99474454; called by muse, varscan2
- HDGFL1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs1160115701, COSV57753175; called by muse, mutect2, varscan2
- HEATR5B | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs757984204, COSV99250147; called by muse, mutect2, varscan2
- HMCN1 | c.9080T>C p.V3027A | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as COSV99634979; called by muse, mutect2, varscan2
- HNF1A | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as CM023589, COSV57465633, COSV99982960; called by muse, mutect2, varscan2
- HSD11B1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99808355; called by muse, mutect2
- IL9R | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99730175; called by muse, mutect2, varscan2
- KATNB1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1567905235, COSV101109344; called by muse, mutect2, varscan2
- KBTBD6 | c.1837dup p.C613Lfs*12 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as rs1417700999; called by mutect2, varscan2
- KCNA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52906401, COSV99364165; called by muse, mutect2, varscan2
- KIF17 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.024); catalogued as COSV56118004, COSV99929668; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLHDC3 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55064007; called by muse, mutect2, varscan2
- KMT5A | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100389606; called by muse, mutect2, varscan2
- KNDC1 | c.3319G>A p.V1107I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs558007261, COSV58833862; called by muse, mutect2, varscan2
- KRT20 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1192320676, COSV51424303; called by muse, mutect2, varscan2
- KRT85 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs781569242, COSV57736074; called by muse, mutect2, varscan2
- KSR1 | c.1870C>A p.H624N (on ENST00000644974 / NM_001367810.1; = p.H509N on NM_014238.2) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99260714; called by muse, mutect2, varscan2
- LAMA5 | c.7838C>T p.A2613V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs370074478; called by muse, mutect2, varscan2
- LAMB4 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1361858682, COSV99225435; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | catalogued as rs775423572; called by mutect2, varscan2
- LIPJ | c.830G>T p.W277L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100905926; called by muse, mutect2, varscan2
- LRRTM1 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377040455; called by muse, mutect2, varscan2
- MACF1 | c.7820G>C p.G2607A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99246552; called by muse, mutect2, varscan2
- MAGEB6B | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773221084; called by muse, varscan2
- MAMLD1 | c.1564A>T p.M522L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV99476539; called by muse, mutect2
- MAP3K9 | c.2416C>T p.R806W (on ENST00000554752 / NM_001284230.1; = p.R820W on NM_033141.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs754111307, COSV67122646; called by muse, mutect2, varscan2
- MAST2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs372615184; called by muse, mutect2, varscan2
- MB21D2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs953443071, COSV101165174, COSV66664896; called by muse, mutect2
- MDC1 | c.5414C>A p.P1805H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100903060; called by muse, mutect2
- MRPL35 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755014014, COSV99383304; called by muse, mutect2, varscan2
- MSL2 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99388080; called by muse, mutect2, varscan2
- MST1R | c.3635G>A p.R1212Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1008363508, COSV56576561; called by muse, mutect2, varscan2
- MTFR1 | c.162T>G p.F54L | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100050387; called by muse, mutect2, varscan2
- MYO10 | c.5641C>T p.R1881W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759162257, COSV99946176; called by muse, mutect2, varscan2
- MYO16 | c.3919C>T p.R1307W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747453615, COSV100697146, COSV100697218; called by muse, mutect2, varscan2
- MYO1C | c.3083G>C p.G1028A (on ENST00000648651 / NM_001080779.2; = p.G993A on NM_033375.5) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV100704496; called by muse, mutect2, varscan2
- NADK2 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99237817; called by muse, mutect2, varscan2
- NAV3 | c.3875C>T p.S1292L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99895011; called by muse, mutect2
- NCAM1 | c.1243G>A p.A415T (on ENST00000316851 / NM_181351.5; = p.A405T on NM_000615.7) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1555117373, COSV100377142, COSV57517141; called by muse, mutect2, varscan2
- NCOA5 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs777887637, COSV51645044; called by muse, mutect2, varscan2
- NEGR1 | c.1046A>C p.K349T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV100165826; called by muse, mutect2, varscan2
- NEK10 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs371393406; called by muse, mutect2, varscan2
- NKTR | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV99236284, COSV99236371; called by muse, mutect2
- NOC4L | c.1369A>G p.N457D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV100400216; called by muse, mutect2, varscan2
- NOS1 | c.540del p.R181Gfs*29 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1306362358; called by mutect2, pindel, varscan2
- NUP93 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV100360474; called by muse, mutect2, varscan2
- NWD1 | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs371297297; called by muse, mutect2, varscan2
- OLFML3 | c.250T>G p.S84A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100233232; called by muse, mutect2, varscan2
- OR1C1 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101376274; called by muse, mutect2, varscan2
- OR4S1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100180334; called by muse, mutect2, varscan2
- OR56B4 | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV100337692; called by muse, mutect2, varscan2
- OR5D18 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100450878; called by muse, varscan2
- OTULIN | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99420019; called by muse, mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 32/165 reads (19%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PCDHGB2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as COSV53970037; called by muse, mutect2, varscan2
- PCDHGB4 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV99546078; called by muse, varscan2
- PCDHGC5 | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV99342164; called by muse, mutect2, varscan2
- PDZD2 | c.4505C>T p.S1502L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373613274; called by muse, mutect2, varscan2
- PITPNM2 | c.2549C>T p.T850M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs758915042, COSV99040309; called by muse, mutect2, varscan2
- PITPNM2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs772008716, COSV99759593; called by muse, mutect2, varscan2
- PLAT | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs61231575, COSV54277285, COSV99535386; called by muse, mutect2, varscan2
- PLEC | c.7250C>T p.A2417V (on ENST00000322810 / NM_201380.4; = p.A2307V on NM_000445.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.382); catalogued as COSV59651565; called by muse, mutect2, varscan2
- PLEKHG5 | c.2317A>G p.T773A (on ENST00000400915 / NM_001042663.3; = p.T736A on NM_020631.6) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs1460920482, COSV100557120; called by muse, mutect2
- PLPPR2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1333309746, COSV99264704; called by muse, mutect2, varscan2
- POU6F1 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100374898; called by muse, mutect2, varscan2
- PPM1H | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs754740224, COSV99956459; called by muse, mutect2, varscan2
- PPP1R13B | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs761642759, COSV52451063; called by muse, mutect2, varscan2
- PRKG1 | c.874G>T p.D292Y | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV100907486; called by muse, mutect2
- PRRC2B | c.5579G>A p.R1860H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1277243391, COSV100261130; called by muse, mutect2, varscan2
- PSD2 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384967216, COSV51197953; called by muse, mutect2, varscan2
- PTK2B | c.1833C>T p.F611= | Splice Region (SNP) | VAF 14/29 reads (48%) | catalogued as rs751633425, COSV100594398; called by muse, varscan2
- PTPRK | c.3146C>T p.P1049L (on ENST00000368215 / NM_001291984.2; = p.P1050L on NM_002844.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100951530; called by muse, mutect2, varscan2
- PTPRS | c.5804C>T p.A1935V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326058191, COSV53619028; called by muse, mutect2, varscan2
- PXT1 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV60316809; called by muse, mutect2, varscan2
- R3HDM1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1350193295, COSV51523967; called by muse, mutect2, varscan2
- RALGAPA2 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99174902; called by muse, mutect2, varscan2
- RARS1 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249122899, COSV51562661; called by muse, mutect2, varscan2
- RGMA | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224637; called by muse, mutect2, varscan2
- RNF25 | c.1203G>T p.K401N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99829196; called by muse, mutect2
- RPAP1 | c.4039C>T p.R1347W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs756204073, COSV99779285; called by muse, mutect2, varscan2
- RPH3AL | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV100047818; called by muse, mutect2
- RPL5 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV100240481; called by muse, mutect2, varscan2
- RREB1 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.148); catalogued as rs778172996, COSV100619808; called by muse, mutect2, varscan2
- RSPH4A | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as COSV57635252; called by muse, mutect2
- RTEL1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs750794827, COSV100541907; called by muse, varscan2
- SCAF4 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs765352495, COSV99742094; called by muse, mutect2, varscan2
- SCAMP2 | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99174002; called by muse, mutect2, varscan2
- SCN2A | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768403673, COSV51840549; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs768388757; called by pindel, varscan2
- SELENOM | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1258877849, COSV100294879; called by muse, mutect2
- SELL | c.57A>C p.K19N (on ENST00000650983; = p.K6N on NM_000655.5) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV99357794; called by muse, mutect2
- SEMA3D | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.784); catalogued as COSV99407346; called by muse, mutect2, varscan2
- SEMA6A | c.473A>T p.E158V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963728; called by muse, mutect2, varscan2
- SENP3 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); catalogued as rs771421264, COSV99547977; called by muse, mutect2, varscan2
- SEPTIN4 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319265406, COSV100051398; called by muse, mutect2
- SFTPC | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV100110096; called by muse, mutect2, varscan2
- SHANK2 | c.4130C>T p.A1377V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs782311249, COSV53594324; ClinVar: likely benign; called by muse, mutect2, varscan2
- SKA3 | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100006518, COSV53433917; called by muse, mutect2, varscan2
- SLC12A2 | c.3442C>T p.R1148W | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99321492; called by muse, mutect2, varscan2
- SLC22A16 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs778848700, COSV57935868; called by muse, mutect2, varscan2
- SLC41A1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs760963832, COSV65651450; called by muse, mutect2, varscan2
- SLC4A5 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61024695; called by muse, mutect2, varscan2
- SLC9A9 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs771359670, COSV57221558; called by muse, mutect2, varscan2
- SMPD2 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99238145; called by muse, mutect2, varscan2
- SMR3A | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs1170103326, COSV99895711, COSV99895834; called by muse, mutect2, varscan2
- SNX8 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs762395749, COSV99771130; called by muse, mutect2, varscan2
- SOAT2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753328369, COSV56860718; called by muse, mutect2, varscan2
- SOWAHB | c.1376G>C p.R459T | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.288); catalogued as COSV100530790; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPHK2 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99709593; called by muse, mutect2
- SPPL2C | c.626A>C p.E209A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100234146; called by muse, mutect2
- SPRY1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1467473390, COSV100201928; called by muse, mutect2
- SPTY2D1 | c.96dup p.D33Rfs*5 | Frame Shift Ins (INS) | VAF 12/76 reads (16%) | catalogued as rs1263882321; called by mutect2, varscan2
- STRADB | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs767850258, COSV99524769; called by muse, mutect2
- SULF1 | c.1878C>G p.I626M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52692208, COSV99484250; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 56/148 reads (38%) | catalogued as rs747003550; called by mutect2, varscan2
- SYN3 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753833714, COSV60502626; called by muse, mutect2, varscan2
- TADA1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs200689473, COSV63310422; called by muse, mutect2, varscan2
- TAF10 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as rs763667789, COSV100196611; called by muse, mutect2, varscan2
- TBC1D22B | c.1430G>A p.W477* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | catalogued as COSV100996918; called by muse, mutect2
- TCOF1 | c.3047G>C p.G1016A (on ENST00000377797 / NM_001135243.1; = p.G939A on NM_000356.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100078274; called by muse, mutect2, varscan2
- TENM2 | c.1583G>A p.R528Q (on ENST00000518659 / NM_001122679.2; = p.R296Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs367902324; called by muse, mutect2, varscan2
- TERF1 | c.1244G>A p.R415Q (on ENST00000276603 / NM_017489.3; = p.R395Q on NM_003218.4) | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749879752, COSV99401232; called by muse, mutect2, varscan2
- THBS3 | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200881809, COSV64250386; called by muse, mutect2, varscan2
- THSD7B | c.3244C>T p.R1082C (on ENST00000272643; = p.R1080C on NM_001316349.2) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as rs1431031275, COSV99757619; called by muse, varscan2
- TLN1 | c.5684G>A p.R1895H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs567336438, COSV100148179; called by muse, mutect2, varscan2
- TMEM132A | c.1757G>A p.R586H (on ENST00000453848 / NM_178031.3; = p.R587H on NM_017870.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs769429539, COSV99137035; called by muse, varscan2
- TMEM260 | c.119T>A p.F40Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99840630; called by muse, mutect2, varscan2
- TMEM266 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs769651494, COSV101189650; called by muse, mutect2, varscan2
- TMEM79 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.937); catalogued as COSV99828102; called by muse, mutect2, varscan2
- TMEM88 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.759); catalogued as COSV99640808; called by muse, mutect2
- TOR4A | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs982736393, COSV100677792; called by muse, mutect2, varscan2
- TOX3 | c.1252T>A p.S418T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV99568086; called by muse, mutect2, varscan2
- TRIM26 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV70983325; called by muse, mutect2, varscan2
- TRIM3 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100624532; called by muse, mutect2, varscan2
- UBA6 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs373643001; called by muse, mutect2, varscan2
- USP2 | c.136_138del p.K46del | In Frame Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs750299284; called by mutect2, pindel, varscan2
- VPS50 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs776743041, COSV52492435; called by muse, mutect2, varscan2
- VSIR | c.677-1G>T p.X226_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99823541; called by muse, mutect2, varscan2
- WASF3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs770264821, COSV58963122; called by muse, mutect2, varscan2
- WBP4 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as rs774564893, COSV101069335; called by muse, mutect2, varscan2
- WDR47 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767448652, COSV100728436, COSV63060679; called by muse, mutect2, varscan2
- WNK3 | c.3635G>T p.S1212I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100672044; called by muse, mutect2, varscan2
- WWP1 | c.2584G>A p.A862T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV99617117; called by muse, mutect2
- ZC3H13 | c.2805G>T p.Q935H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99668835; called by muse, mutect2, varscan2
- ZFPM2 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV101023502; called by muse, mutect2, varscan2
- ZNF146 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100757764; called by muse, mutect2
- ZNF235 | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760045471, COSV52158892; called by muse, mutect2, varscan2
- ZNF341 | c.2242dup p.Q748Pfs*22 (on ENST00000375200 / NM_001282935.1; = p.Q741Pfs*22 on NM_032819.4) | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | catalogued as rs747874764; called by mutect2, varscan2
- ZNF567 | c.1627C>T p.R543C (on ENST00000536254 / NM_001322913.1; = p.R512C on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.744); catalogued as rs201636823; called by muse, mutect2, varscan2
- ANKS3 | c.109del p.L37Wfs*15 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | called by mutect2, pindel, varscan2
- ARID2 | c.3724del p.I1242* | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel
- ATP8A1 | c.243dup p.L82Sfs*11 | Frame Shift Ins (INS) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- C3orf20 | c.229del p.L77Wfs*15 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- CENPH | c.344del p.N115Tfs*16 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, varscan2
- CYP11B1 | c.1026G>T p.Q342H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND2B | c.218del p.P73Qfs*53 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, varscan2
- DENND6A | c.1322dup p.L441Ffs*47 | Frame Shift Ins (INS) | VAF 13/107 reads (12%) | called by mutect2, pindel, varscan2
- DNAH9 | c.12378_12379del p.C4127Qfs*41 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by pindel, varscan2
- EIF2AK3 | c.1556del p.L519Yfs*7 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- EXOC2 | c.25del p.V10* | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- FAM151B | c.756dup p.Q253Tfs*5 | Frame Shift Ins (INS) | VAF 10/103 reads (10%) | called by mutect2, pindel
- FPGT | c.910dup p.I304Nfs*7 | Frame Shift Ins (INS) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- HYDIN | c.13701dup p.F4568Ifs*2 | Frame Shift Ins (INS) | VAF 42/141 reads (30%) | called by mutect2, pindel, varscan2
- ING2 | c.824del p.K275Rfs*32 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- ITSN2 | c.2628del p.K876Nfs*23 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- KATNIP | c.1665dup p.V556Cfs*25 | Frame Shift Ins (INS) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- KIF13B | c.2404dup p.V802Gfs*12 | Frame Shift Ins (INS) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- KRT222 | c.121del p.M41Wfs*8 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- LACTB | c.501_502del p.L169Hfs*17 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- NF1 | c.1882del p.Y628Tfs*3 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- NRK | c.3594del p.K1198Nfs*3 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- PROX1 | c.1780del p.Y594Ifs*10 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | called by mutect2, pindel, varscan2
- PTBP1 | c.80dup p.P28Tfs*16 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- RANBP10 | c.884_887del p.R295Kfs*46 | Frame Shift Del (DEL) | VAF 42/87 reads (48%) | called by mutect2, pindel, varscan2
- SCAMP1 | c.77del p.V26Gfs*26 | Frame Shift Del (DEL) | VAF 42/181 reads (23%) | called by mutect2, pindel, varscan2
- TERF1 | c.1049dup p.K351Efs*9 (on ENST00000276603 / NM_017489.3; = p.K331Efs*9 on NM_003218.4) | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- UBE3A | c.2064dup p.G689Wfs*2 | Frame Shift Ins (INS) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- USP34 | c.5403del p.K1801Nfs*14 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- WWC1 | c.1273del p.S425Vfs*107 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.879del p.S294Afs*13 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- ZNF131 | c.979del p.I327Ffs*45 (on ENST00000509156 / NM_001330707.2; = p.I293Ffs*45 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ABCA12 | c.5844T>C p.L1948= (on ENST00000272895 / NM_173076.3; = p.L1630= on NM_015657.3) | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99791753; called by muse, mutect2, varscan2
- ABCC5 | c.375G>A p.K125= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99657518; called by muse, mutect2
- AEBP1 | c.2784T>C p.S928= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs773051868, COSV99789080; called by muse, varscan2
- ANLN | c.1710T>C p.S570= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99732794; called by muse, mutect2, varscan2
- ARHGAP45 | c.1755G>A p.A585= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57430623; called by muse, mutect2
- ARHGEF17 | c.1419G>A p.T473= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as rs1202605113, COSV55232657; called by muse, mutect2, varscan2
- BAHCC1 | c.1884C>T p.D628= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs782221659, COSV100312006; called by muse, mutect2, varscan2
- CAMTA2 | c.2529G>A p.S843= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs765210809, COSV99236787; called by muse, varscan2
- CELA2A | c.174C>T p.C58= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs764179482, COSV100657609; called by muse, mutect2, varscan2
- CEP350 | c.4140G>A p.L1380= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100855166; called by muse, mutect2, varscan2
- CFAP45 | c.495G>A p.L165= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100928662; called by muse, mutect2, varscan2
- CIB4 | c.147G>A p.T49= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs376716139; called by muse, mutect2, varscan2
- CPT1B | c.1281C>A p.S427= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100376823; called by muse, mutect2, varscan2
- EIF2S2 | c.315T>C p.S105= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100895004, COSV100895014; called by muse, mutect2, varscan2
- EPHA3 | c.1245G>A p.V415= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs771278897, COSV100348313; called by muse, mutect2, varscan2
- FAM86B1 | c.735C>T p.Y245= | Silent (SNP) | VAF 25/235 reads (11%) | catalogued as rs200121631, COSV100392466; called by muse, mutect2, varscan2
- FAT1 | c.13698C>T p.S4566= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs374285602; called by muse, mutect2, varscan2
- GREB1 | c.4386G>A p.A1462= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs541354837, COSV52182987; called by muse, mutect2, varscan2
- HIRA | c.1536C>T p.F512= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs759228734, COSV54274465; called by muse, mutect2, varscan2
- IPO4 | c.1152C>T p.G384= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs752936115, COSV99938253; called by muse, varscan2
- IZUMO2 | c.213C>T p.N71= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV53230125; called by muse, mutect2, varscan2
- KEAP1 | c.234C>T p.D78= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs771599341, COSV50268131; called by muse, mutect2, varscan2
- KIF17 | c.504C>T p.G168= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs144285910, COSV99929670; called by muse, varscan2
- KRT6A | c.390C>T p.C130= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs777003645, COSV58105684; called by muse, mutect2, varscan2
- LAMC1 | c.327C>T p.Y109= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99280352; called by muse, mutect2, varscan2
- LILRA2 | c.798C>T p.R266= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV99253887; called by muse, mutect2
- LIMK1 | c.375G>A p.T125= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs782070319, COSV60281528; called by muse, mutect2, varscan2
- LRP1B | c.2445C>T p.G815= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs1558795324, COSV101250735, COSV101260275; called by muse, mutect2, varscan2
- MACROH2A1 | c.150C>T p.A50= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1011940579, COSV56896071; called by muse, mutect2, varscan2
- MAPT | c.1548C>T p.Y516= (on ENST00000262410 / NM_001377265.1; = p.Y441= on NM_016835.4) | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs556489804, COSV52241139, COSV52244709; called by muse, mutect2, varscan2
- MPZL1 | c.663C>T p.S221= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs749835317, COSV100850406; called by muse, mutect2, varscan2
- MTCL1 | c.2934C>T p.H978= (on ENST00000306329 / NM_001378206.1; = p.H618= on NM_015210.4) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs762293612, COSV100095475; called by muse, mutect2, varscan2
- MYH9 | c.3912C>T p.S1304= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs1419369426, COSV53392784; called by muse, mutect2, varscan2
- NKD1 | c.708C>T p.D236= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99194118; called by muse, mutect2, varscan2
- NLGN3 | c.1719G>A p.P573= (on ENST00000358741 / NM_181303.2; = p.P553= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs370836243, COSV62441895; called by muse, mutect2, varscan2
- NT5C1B | c.369A>G p.R123= (on ENST00000359846 / NM_001199086.2; = p.R63= on NM_033253.4) | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100410270; called by muse, mutect2, varscan2
- OR2T4 | c.997C>T p.L333= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV100822603, COSV63544379; called by muse, mutect2, varscan2
- PCDH18 | c.861T>C p.S287= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100787498; called by muse, mutect2, varscan2
- PCLO | c.8727C>T p.V2909= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs1326525804, COSV61632916; called by muse, mutect2, varscan2
- PCSK4 | c.1005C>T p.S335= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs146576658; called by muse, mutect2, varscan2
- PDE1B | c.1056G>A p.Q352= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99672949; called by muse, mutect2
- PDE4B | c.1780C>A p.R594= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100304809, COSV58468345, COSV58486518; called by muse, mutect2, varscan2
- PHC3 | c.597G>A p.S199= (on ENST00000494943 / NM_001308116.2; = p.S211= on NM_024947.4) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs780182806, COSV63051652; called by muse, mutect2, varscan2
- PLD2 | c.2223C>T p.H741= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs755916788; called by muse, varscan2
- PLD3 | c.1272C>T p.R424= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs778413823, COSV52526540; called by muse, mutect2, varscan2
- POSTN | c.1524C>A p.R508= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV101123482; called by muse, mutect2
- PPP1R3C | c.129C>T p.Y43= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs148420815; called by muse, mutect2, varscan2
- PRDM16 | c.2535G>A p.A845= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1004240763, COSV54593675; called by muse, mutect2, varscan2
- PRDM7 | c.564T>A p.G188= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100371343; called by muse, mutect2, varscan2
- RHO | c.468C>T p.G156= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs760667657, COSV56213361; called by muse, mutect2, varscan2
- RIN3 | c.471C>T p.P157= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs750366777, COSV99379962; called by muse, mutect2, varscan2
- SEZ6L | c.528C>T p.S176= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs371054914; called by muse, mutect2, varscan2
- SFSWAP | c.2139C>T p.V713= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs1313109097, COSV55521478; called by muse, mutect2
- SLC12A4 | c.1239C>T p.V413= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs946596957, COSV100312172; called by muse, mutect2, varscan2
- SLC24A4 | c.408C>T p.S136= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs139530271, COSV54117283; called by muse, mutect2, varscan2
- SPTBN1 | c.1791C>T p.D597= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs551964268, COSV61686927; called by muse, mutect2, varscan2
- ST6GAL1 | c.462G>A p.E154= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99399559; called by muse, mutect2, varscan2
- STAB2 | c.456C>T p.D152= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs767507326, COSV101186272; called by muse, mutect2, varscan2
- SYK | c.1659C>T p.S553= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs141667926; called by muse, mutect2, varscan2
- TEX15 | c.7257T>C p.T2419= (on ENST00000256246; = p.T2802= on NM_001350162.2) | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99822039; called by muse, mutect2, varscan2
- TFAP2B | c.412C>A p.R138= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99540781; called by muse, mutect2
- THBS4 | c.372G>A p.R124= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1470097300, COSV100644418, COSV63470450; called by muse, mutect2, varscan2
- TICAM1 | c.1884G>A p.P628= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs773993340, COSV50229775, COSV99941000; called by muse, mutect2, varscan2
- TMEM131 | c.639G>A p.R213= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as COSV99489437; called by muse, mutect2, varscan2
- TMEM259 | c.1161G>A p.A387= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs551309304, COSV99312859; called by muse, mutect2, varscan2
- TUBA3D | c.966C>T p.D322= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs755153413, COSV100342882; called by muse, mutect2, varscan2
- UGT3A2 | c.1407G>A p.T469= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs138782726, COSV56930810; called by muse, mutect2, varscan2
- ZDHHC3 | c.882G>A p.P294= (on ENST00000424952 / NM_001135179.2; = p.P322= on NM_016598.3) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs377350770, COSV56103391; called by muse, mutect2, varscan2
- ZFYVE9 | c.1386C>T p.F462= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99820651; called by muse, mutect2, varscan2
- ZNF526 | c.1737C>T p.G579= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV99725441; called by muse, mutect2
- AC024940.1 | n.3549A>T | RNA (SNP) | VAF 89/371 reads (24%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3548G>T | RNA (SNP) | VAF 88/368 reads (24%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 22/102 reads (22%) | catalogued as rs201441562; called by pindel, varscan2
- CAMK2G | c.947-2082C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99990257; called by muse, mutect2, varscan2
- CTNNA2 | c.1057-79597del | Intron (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- NBPF11 | c.-548-2895G>C | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- NUDCD3 | c.509+16750G>A | Intron (SNP) | VAF 18/53 reads (34%) | catalogued as rs769756544; called by muse, mutect2, varscan2
